Gene-level copy-number profile of tumor specimen TCGA-2G-AAEY-01A from TCGA case TCGA-2G-AAEY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 34.5 years (12,588 days).
Specimen TCGA-2G-AAEY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22860371-0662-45f0-b0d7-4ca192d0f27b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAEY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/a0bcdd3f-0690-4ac0-aa0a-376a92e372b6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,746; copy number 2: 24,794; copy number 3: 22,912; copy number 4: 6,259; copy number 5: 1,129; copy number 6: 369; copy number 7: 1,203; copy number 8: 57; copy number 9: 426; copy number 10: 8.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:112,967–186,136, 5 genes (within-gene range 0–2): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,694 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,294,442–177,349,166, 3 genes, copy number 7: LINC00501, ASS1P7, AC117465.1.
- chr7:71,132,144–81,770,438, 222 genes, copy number 8–10 (broad region; genes not listed).
- chr8:19,084,992–19,396,218, 8 genes, copy number 9: AC100849.1, AC100849.2, AC068880.1, AC068880.3, AC068880.2, AC068880.5, SH2D4A, AC068880.4.
- chr8:46,028,804–72,470,972, 382 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–24,562,544, 618 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:25,004,342–34,249,958, 200 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:38,078,529–49,771,136, 261 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
